Somatic mutation profile of tumor specimen TCGA-ZF-AA4V-01A (aliquot TCGA-ZF-AA4V-01A-11D-A38G-08) from TCGA case TCGA-ZF-AA4V, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 66.9 years (24,448 days).
Specimen TCGA-ZF-AA4V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba87b4c3-c1f3-43e9-b424-261ae275e4ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZF-AA4V-10A (Blood Derived Normal), aliquot TCGA-ZF-AA4V-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8f9d424a-42c0-4daf-b5b7-3663b5eeb3bb

The open-access MAF lists 787 somatic variants for this specimen: 544 protein-altering or splice-affecting, 219 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 478, Silent 219, Nonsense Mutation 35, Frame Shift Del 10, Intron 9, Splice Site 9, Splice Region 7, 5'UTR 4, 3'UTR 3, RNA 3, 3'Flank 3, In Frame Del 2.

Variants (750 of 787; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 52/278 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ERCC2 | c.215A>G p.Y72C | Missense Mutation (SNP) | VAF 31/159 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55538855, COSV99676553; called by muse, mutect2, varscan2
- HNF1B | c.1561C>T p.Q521* | Nonsense Mutation (SNP) | VAF 5/61 reads (8%) | catalogued as rs1057524479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- RB1 | c.1215+1G>A p.X405_splice | Splice Site (SNP) | VAF 14/58 reads (24%) | hotspot (GDC flag); catalogued as rs587776783, CS890133, CS982341, COSV57294684, COSV57294939, COSV57306748; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TMEM131 | c.3955G>A p.E1319K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | hotspot (GDC flag); SIFT tolerated, low confidence (0.19); PolyPhen benign (0.039); catalogued as COSV51770253, COSV51770622, COSV51771645; called by muse, mutect2, varscan2
- AAGAB | c.172A>G p.I58V | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs1157491698, COSV56016051; called by muse, mutect2, varscan2
- AATK | c.4090G>A p.E1364K (on ENST00000326724 / NM_001080395.3; = p.E1261K on NM_004920.2) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.003); catalogued as COSV100353401; called by muse, mutect2
- ABCC12 | c.2751C>A p.D917E | Missense Mutation (SNP) | VAF 61/112 reads (54%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.973); catalogued as COSV100253473, COSV60911892; called by muse, mutect2, varscan2
- ABL2 | c.3205C>G p.L1069V (on ENST00000502732 / NM_007314.4; = p.L1054V on NM_005158.5) | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV61011334; called by muse, mutect2, varscan2
- AC008397.2 | c.1217C>T p.T406M | Missense Mutation (SNP) | VAF 69/146 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.559); catalogued as rs148755672, COSV53204890; called by muse, mutect2, varscan2
- ACAA1 | c.943G>T p.D315Y | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); catalogued as COSV57170636; called by muse, mutect2
- ACER2 | c.812C>T p.S271L | Missense Mutation (SNP) | VAF 29/199 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs778943876, COSV61820393; called by muse, mutect2, varscan2
- ACKR1 | c.25G>C p.E9Q | Missense Mutation (SNP) | VAF 18/320 reads (6%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.496); catalogued as COSV63671779; called by muse, mutect2
- ACMSD | c.58-1G>A p.X20_splice | Splice Site (SNP) | VAF 22/75 reads (29%) | catalogued as COSV51605632; called by muse, mutect2, varscan2
- ACO1 | c.1252G>A p.D418N | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV59377098; called by muse, mutect2, varscan2
- ACSS3 | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV54085632, COSV54097587; called by muse, mutect2, varscan2
- ADAM30 | c.2285C>A p.S762Y | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.024); catalogued as COSV65560436; called by muse, mutect2, varscan2
- ADD3 | c.785A>G p.Y262C | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.26); catalogued as rs752394118, COSV53320310; called by muse, mutect2, varscan2
- ADGRL2 | c.2582G>C p.C861S (on ENST00000370717 / NM_001366005.1; = p.C848S on NM_012302.4) | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs369954151, COSV54689781; called by muse, mutect2, varscan2
- ADIPOQ | c.329T>C p.V110A | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV57858515; called by muse, mutect2, varscan2
- ADRA2C | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.03); catalogued as COSV100342873; called by muse, mutect2
- AFAP1 | c.904+1G>A p.X302_splice | Splice Site (SNP) | VAF 18/75 reads (24%) | catalogued as COSV61793452; called by muse, mutect2, varscan2
- AGPAT4 | c.993G>C p.R331S | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1302801141, COSV57243183; called by muse, mutect2, varscan2
- AIPL1 | c.92C>T p.S31F | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs1458100796, COSV51505928; called by muse, mutect2, varscan2
- AKAP8L | c.1513A>G p.M505V | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs376471318; called by muse, mutect2, varscan2
- ALDH1B1 | c.1057G>C p.E353Q | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); catalogued as COSV66619284; called by muse, mutect2, varscan2
- ALX1 | c.713C>T p.S238L | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.833); catalogued as COSV57491259; called by muse, mutect2, varscan2
- AMH | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as rs1376893013, COSV99678145; called by muse, mutect2
- ANK2 | c.6763G>C p.E2255Q | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.018); catalogued as COSV52147613; called by muse, mutect2, varscan2
- ANKLE2 | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV61707924; called by muse, mutect2, varscan2
- ANO8 | c.2947C>G p.P983A | Missense Mutation (SNP) | VAF 36/180 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV50173296; called by muse, mutect2, varscan2
- ANXA1 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.051); catalogued as rs1308023506, COSV57410458; called by muse, mutect2, varscan2
- ANXA5 | c.475G>T p.A159S | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as COSV56638333; called by muse, mutect2, varscan2
- APOBEC4 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as rs139605657; called by muse, mutect2, varscan2
- ARG2 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 53/72 reads (74%) | SIFT tolerated (0.06); PolyPhen benign (0.096); catalogued as COSV53619124; called by muse, mutect2, varscan2
- ARHGAP21 | c.5252G>A p.R1751K | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV57602499; called by muse, mutect2, varscan2
- ARHGAP30 | c.3257C>A p.S1086* (on ENST00000368013 / NM_001025598.2; = p.S875* on NM_181720.3) | Nonsense Mutation (SNP) | VAF 28/661 reads (4%) | catalogued as COSV100920561; called by muse, mutect2
- ARHGAP31 | c.1654C>G p.P552A | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs370183659, COSV51789497; called by muse, mutect2, varscan2
- ARHGEF12 | c.1279C>T p.Q427* | Nonsense Mutation (SNP) | VAF 5/31 reads (16%) | catalogued as COSV100755290; called by muse, mutect2, varscan2
- ARID1B | c.4919G>A p.W1640* | Nonsense Mutation (SNP) | VAF 157/351 reads (45%) | catalogued as rs1554236627, COSV51666242; called by muse, mutect2, varscan2
- ARPC5 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as rs370723137, COSV54170871; called by muse, mutect2, varscan2
- ARPP19 | c.214A>C p.M72L | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as COSV51119118; called by muse, mutect2, varscan2
- ART3 | c.392A>G p.Y131C | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs769998982, COSV61913151; called by muse, mutect2, varscan2
- ASAP2 | c.2152G>A p.D718N | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.156); catalogued as COSV55627715; called by muse, mutect2, varscan2
- ASTN2 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); catalogued as rs934754146, COSV57829719; called by muse, mutect2
- ATAD5 | c.1711G>A p.D571N | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.212); catalogued as COSV58972226; called by muse, mutect2, varscan2
- ATG2B | c.4787T>C p.V1596A | Missense Mutation (SNP) | VAF 81/112 reads (72%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV55889469; called by muse, mutect2, varscan2
- ATG2B | c.1502C>T p.S501L | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT tolerated (1); PolyPhen probably damaging (0.991); catalogued as COSV63421828; called by muse, mutect2, varscan2
- ATP13A4 | c.1685T>A p.F562Y | Missense Mutation (SNP) | VAF 62/141 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV55066300; called by muse, mutect2, varscan2
- BCAR1 | c.1579G>C p.G527R | Missense Mutation (SNP) | VAF 48/67 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV50778816; called by muse, mutect2, varscan2
- BCL11B | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 43/64 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV61733579; called by muse, mutect2, varscan2
- BEST3 | c.1063T>C p.C355R | Missense Mutation (SNP) | VAF 30/780 reads (4%) | SIFT tolerated (0.66); PolyPhen benign (0.014); catalogued as COSV58299036; called by muse, mutect2
- BFAR | c.198G>C p.K66N | Missense Mutation (SNP) | VAF 54/185 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as COSV55492589; called by muse, mutect2, varscan2
- BIRC3 | c.471G>C p.L157F | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV54815162, COSV99679966; called by muse, mutect2, varscan2
- BMP1 | c.2833G>A p.E945K | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.314); catalogued as COSV60528311; called by muse, mutect2, varscan2
- BMP2 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV101122129; called by muse, mutect2
- BMPR1B | c.550C>T p.Q184* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as COSV99216373; called by muse, mutect2, varscan2
- BRCA2 | c.5176G>A p.E1726K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.526); catalogued as COSV66448649; called by muse, mutect2, varscan2
- BTAF1 | c.1431G>C p.W477C | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV56430234; called by muse, mutect2, varscan2
- BTBD8 | c.200C>T p.T67I | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.624); catalogued as COSV61545104; called by muse, mutect2, varscan2
- BTC | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV67547279; called by muse, mutect2, varscan2
- C19orf44 | c.439A>C p.T147P | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.019); catalogued as COSV55610252; called by muse, mutect2, varscan2
- C1orf43 | c.500G>A p.G167E (on ENST00000368521 / NM_001297718.2; = p.G133E on NM_015449.4) | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62965876; called by muse, mutect2, varscan2
- C21orf91 | c.96C>G p.F32L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53032459; called by muse, mutect2, varscan2
- C5orf34 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.266); catalogued as rs1181233952, COSV60928958; called by muse, mutect2, varscan2
- CACNG3 | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 36/267 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV50064253; called by muse, mutect2, varscan2
- CAMTA1 | c.5015G>T p.G1672V | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99276584; called by muse, mutect2, varscan2
- CARMIL3 | c.3001C>A p.Q1001K | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as rs1366046012, COSV57724881; called by muse, mutect2, varscan2
- CARNMT1 | c.563T>A p.I188N | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV65190109; called by muse, mutect2, varscan2
- CASQ1 | c.838A>G p.M280V | Missense Mutation (SNP) | VAF 314/362 reads (87%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs531978131, COSV63623914; called by muse, mutect2, varscan2
- CCDC14 | c.1681C>G p.L561V (on ENST00000488653; = p.L513V on NM_022757.5) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV59943065; called by muse, mutect2, varscan2
- CCDC151 | c.1756C>G p.H586D | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV62697256; called by muse, mutect2, varscan2
- CCDC28A | c.164T>A p.M55K | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV60424520; called by muse, mutect2, varscan2
- CCDC85A | c.485A>G p.N162S | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68147821; called by muse, mutect2, varscan2
- CCNT2 | c.367G>C p.D123H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); catalogued as COSV51471179; called by muse, mutect2, varscan2
- CD48 | c.369C>G p.I123M | Missense Mutation (SNP) | VAF 44/1134 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV63566017; called by muse, mutect2
- CDC123 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1286541186, COSV55396549; called by muse, mutect2, varscan2
- CDH10 | c.1187A>G p.D396G | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.626); catalogued as COSV52570920; called by muse, mutect2, varscan2
- CDK12 | c.2083C>T p.Q695* | Nonsense Mutation (SNP) | VAF 18/66 reads (27%) | catalogued as COSV101420578; called by muse, mutect2, varscan2
- CEMIP | c.3853G>C p.D1285H | Missense Mutation (SNP) | VAF 54/225 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.781); catalogued as COSV54988569; called by muse, mutect2, varscan2
- CENPU | c.1221C>G p.I407M | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV55656511, COSV55659405; called by muse, mutect2
- CFAP251 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV55838927; called by muse, mutect2, varscan2
- CHD6 | c.2305G>A p.D769N | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV58554147; called by muse, mutect2, varscan2
- CHD9 | c.5803C>G p.R1935G | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54607929; called by muse, mutect2, varscan2
- CHFR | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs1190933998, COSV57172241; called by muse, mutect2, varscan2
- CLHC1 | c.442G>T p.D148Y | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV63427060; called by muse, mutect2, varscan2
- CLRN1 | c.431C>T p.S144L (on ENST00000327047 / NM_174878.3; = p.S68L on NM_052995.2) | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as COSV55804726; called by mutect2, varscan2
- CNKSR2 | c.57G>A p.W19* | Nonsense Mutation (SNP) | VAF 23/50 reads (46%) | catalogued as COSV99670198; called by muse, mutect2, varscan2
- CNTRL | c.4483G>A p.D1495N | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.444); catalogued as rs778554732, COSV53043604; called by muse, mutect2, varscan2
- COG7 | c.595C>T p.Q199* | Nonsense Mutation (SNP) | VAF 27/171 reads (16%) | catalogued as COSV100207901; called by muse, mutect2, varscan2
- COL12A1 | c.6383G>A p.W2128* | Nonsense Mutation (SNP) | VAF 21/63 reads (33%) | catalogued as COSV100486254, COSV100486781; called by muse, mutect2, varscan2
- COX15 | c.540G>C p.M180I | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as COSV50011907; called by muse, mutect2, varscan2
- CPA3 | c.40C>T p.L14F | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV56043530; called by muse, mutect2, varscan2
- CPS1 | c.36G>C p.R12S | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV51802782, COSV99242540; called by muse, mutect2, varscan2
- CPXM1 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV66044671; called by muse, varscan2
- CPXM1 | c.1112T>C p.L371P | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66044675; called by muse, varscan2
- CREB3L3 | c.1327C>G p.P443A | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as COSV50173847; called by muse, mutect2, varscan2
- CRTC1 | c.570G>C p.E190D | Missense Mutation (SNP) | VAF 69/304 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV58716353, COSV58716653; called by muse, mutect2, varscan2
- CSMD2 | c.205C>T p.Q69* | Nonsense Mutation (SNP) | VAF 19/52 reads (37%) | catalogued as rs867259644, COSV53934021; called by muse, mutect2, varscan2
- CTNNA2 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 38/243 reads (16%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.47); catalogued as rs1192427315, COSV63548744; called by muse, mutect2, varscan2
- CUBN | c.9464A>G p.Q3155R | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.344); catalogued as COSV64708557; called by muse, mutect2, varscan2
- CUL4B | c.329C>T p.S110F | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.037); catalogued as COSV100340919, COSV60684215; called by muse, mutect2, varscan2
- CWH43 | c.1498C>T p.H500Y | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56936183, COSV56936996; called by muse, mutect2, varscan2
- CYBC1 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 60/99 reads (61%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); catalogued as COSV60062917; called by muse, mutect2, varscan2
- CYFIP2 | c.528C>A p.N176K | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as rs1422812751, COSV59029048; called by muse, mutect2, varscan2
- CYP2C18 | c.767A>T p.D256V | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53669863; called by muse, mutect2, varscan2
- DCLK2 | c.1129G>C p.E377Q | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.051); catalogued as COSV56199912; called by muse, mutect2, varscan2
- DCN | c.151G>C p.G51R | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.342); catalogued as COSV50006129; called by muse, mutect2, varscan2
- DENND4C | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.238); catalogued as COSV66821539; called by muse, mutect2, varscan2
- DGKH | c.1081C>T p.Q361* | Nonsense Mutation (SNP) | VAF 14/36 reads (39%) | catalogued as rs1242345325, COSV99819778; called by muse, mutect2, varscan2
- DGKK | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs782206353, COSV101052905; called by muse, mutect2
- DHTKD1 | c.2330C>T p.S777L | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1403186509, COSV53801864; called by muse, mutect2, varscan2
- DHX16 | c.422C>T p.S141F | Missense Mutation (SNP) | VAF 151/259 reads (58%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); catalogued as rs140342281; called by muse, mutect2, varscan2
- DHX30 | c.1439G>A p.R480Q (on ENST00000445061 / NM_138615.3; = p.R441Q on NM_014966.3) | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.044); catalogued as rs1227423432, COSV53135462; called by muse, mutect2, varscan2
- DHX34 | c.2792C>G p.A931G | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV60894440; called by muse, mutect2, varscan2
- DHX57 | c.2618T>C p.F873S | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1330989391, COSV54882646; called by muse, mutect2, varscan2
- DHX9 | c.463C>G p.Q155E | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.109); catalogued as COSV62358314; called by muse, mutect2, varscan2
- DLGAP3 | c.2879C>T p.S960L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52391674; called by muse, mutect2, varscan2
- DMGDH | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.283); catalogued as rs145775047; called by muse, mutect2, varscan2
- DMRT3 | c.1244C>T p.S415F | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as COSV51902438; called by muse, mutect2, varscan2
- DNAH1 | c.8356T>C p.S2786P | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.139); catalogued as rs1224275778, COSV101327320; called by muse, mutect2, varscan2
- DNAH12 | c.515A>G p.E172G | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV60855670; called by muse, mutect2, varscan2
- DNAH3 | c.7080C>A p.S2360R | Missense Mutation (SNP) | VAF 71/189 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.319); catalogued as rs1233082644, COSV54505328; called by muse, mutect2, varscan2
- DNAH5 | c.8285C>T p.S2762F | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1242293300, COSV54205725; called by muse, mutect2, varscan2
- DNAH7 | c.1180G>T p.V394F | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.049); catalogued as rs1463168531, COSV56753234, COSV56779367; called by muse, mutect2, varscan2
- DNAJA1 | c.61G>C p.E21Q | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.654); catalogued as rs753974164, COSV58309756; called by muse, mutect2, varscan2
- DNAJA1 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as COSV58309762; called by muse, mutect2, varscan2
- DNTT | c.328T>C p.C110R | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.872); catalogued as COSV64522662; called by muse, mutect2, varscan2
- DOC2A | c.1096C>G p.R366G | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV58750654; called by muse, varscan2
- DPP9 | c.987G>A p.K329= (on ENST00000598800; = p.K358= on NM_139159.5) | Splice Region (SNP) | VAF 12/34 reads (35%) | catalogued as COSV53589378; called by muse, mutect2, varscan2
- DPPA4 | c.14C>A p.S5Y | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.011); catalogued as COSV59509390; called by muse, mutect2, varscan2
- DPYSL4 | c.1110+1G>C p.X370_splice | Splice Site (SNP) | VAF 15/29 reads (52%) | catalogued as COSV58306008, COSV58307277; called by muse, mutect2, varscan2
- DTL | c.470G>T p.C157F | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); catalogued as COSV65341739; called by muse, mutect2, varscan2
- DUSP11 | c.575A>G p.D192G | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.059); catalogued as COSV55593754; called by muse, mutect2, varscan2
- DUSP12 | c.459G>A p.K153= | Splice Region (SNP) | VAF 9/53 reads (17%) | catalogued as COSV63411124; called by muse, mutect2, varscan2
- DYNC1H1 | c.9768G>A p.M3256I | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0.113); catalogued as COSV64134631; called by muse, mutect2, varscan2
- DZIP1L | c.465G>C p.Q155H | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59519346; called by muse, mutect2, varscan2
- E2F8 | c.1657A>C p.T553P | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.203); catalogued as COSV51462054; called by muse, mutect2, varscan2
- ECPAS | c.4717G>T p.G1573* | Nonsense Mutation (SNP) | VAF 42/231 reads (18%) | catalogued as COSV99399544; called by muse, mutect2, varscan2
- EHBP1 | c.1553G>A p.R518Q | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50416121, COSV50430086; called by muse, mutect2, varscan2
- EIF2AK2 | c.262A>G p.T88A | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as COSV51794808; called by muse, mutect2, varscan2
- EIF2B5 | c.534G>C p.L178F (on ENST00000647909; = p.L170F on NM_003907.3) | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.443); catalogued as COSV56603723; called by muse, mutect2, varscan2
- EP300 | c.4730C>T p.S1577F | Missense Mutation (SNP) | VAF 55/166 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54326999; called by muse, mutect2, varscan2
- EPHB2 | c.1309T>C p.S437P | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.945); catalogued as COSV65860139; called by muse, mutect2, varscan2
- ERC2 | c.1589T>C p.M530T | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV55602903; called by muse, mutect2, varscan2
- ERCC6L | c.176G>C p.R59T | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV57819494; called by muse, mutect2, varscan2
- ERLIN2 | c.85_88del p.G29Ifs*12 | Frame Shift Del (DEL) | VAF 17/50 reads (34%) | catalogued as COSV52419361; called by mutect2, pindel, varscan2
- ESYT1 | c.2260G>C p.E754Q | Missense Mutation (SNP) | VAF 80/204 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.747); catalogued as COSV57271775; called by muse, mutect2, varscan2
- EVC2 | c.231C>A p.D77E | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.014); catalogued as rs776531365, COSV60388298; called by muse, mutect2, varscan2
- EXOC4 | c.2266A>T p.I756F | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.852); catalogued as rs745992432, COSV54084819; called by muse, mutect2, varscan2
- FAF2 | c.869G>A p.R290K | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56129835; called by muse, varscan2
- FAM189A2 | c.953C>T p.S318L | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs764949793, COSV57383731; called by muse, mutect2, varscan2
- FAM221B | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 36/256 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV65073683; called by muse, mutect2, varscan2
- FAM72A | c.262C>A p.P88T | Missense Mutation (SNP) | VAF 72/201 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV57917900, COSV57918312; called by muse, varscan2
- FASTKD3 | c.1613G>A p.R538K | Missense Mutation (SNP) | VAF 90/208 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1356735865, COSV52948651; called by muse, mutect2, varscan2
- FAT4 | c.6158C>T p.S2053F | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58672697; called by muse, mutect2, varscan2
- FAT4 | c.8950C>G p.Q2984E | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.82); PolyPhen benign (0.055); catalogued as COSV58672717; called by muse, mutect2, varscan2
- FCHSD2 | c.1747G>A p.D583N | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.871); catalogued as COSV60806891; called by muse, mutect2, varscan2
- FER | c.1280C>T p.S427L | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.977); catalogued as rs1189739159, COSV99814240; called by muse, mutect2
- FKRP | c.1166A>G p.E389G | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.186); catalogued as COSV100586740; called by muse, varscan2
- FLG2 | c.2198G>A p.G733D | Missense Mutation (SNP) | VAF 114/3238 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); catalogued as COSV66166821; called by muse, mutect2
- FOXD4 | c.1226C>G p.S409W | Missense Mutation (SNP) | VAF 64/108 reads (59%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs773107660, COSV58698532; called by muse, mutect2, varscan2
- FZD7 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.88); catalogued as rs1438604237, COSV53808382, COSV53810943; called by muse, mutect2, varscan2
- GAS6 | c.1973C>T p.A658V | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1008695454, COSV59847557; called by muse, varscan2
- GAS6 | c.1930A>G p.M644V | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as rs747147158, COSV59847578; called by muse, varscan2
- GDI2 | c.655T>C p.Y219H | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.232); catalogued as COSV66334190; called by muse, mutect2, varscan2
- GDPD3 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53771190; called by muse, mutect2, varscan2
- GOLGA4 | c.3872C>A p.S1291Y | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs201516912, COSV62709365, COSV62712794; called by muse, mutect2, varscan2
- GON4L | c.188C>T p.S63F | Missense Mutation (SNP) | VAF 59/222 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.28); catalogued as COSV55187570, COSV99673999; called by muse, mutect2, varscan2
- GPAM | c.979G>T p.A327S | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.482); catalogued as COSV62080335; called by muse, mutect2, varscan2
- GPR141 | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 47/231 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV57731373; called by muse, mutect2, varscan2
- GRAMD2B | c.1289A>G p.N430S | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.084); catalogued as COSV53505998; called by muse, mutect2, varscan2
- GREB1 | c.1825+1G>T p.X609_splice | Splice Site (SNP) | VAF 12/61 reads (20%) | catalogued as COSV52181314; called by muse, mutect2, varscan2
- GRIA2 | c.1444A>G p.N482D | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.542); catalogued as rs1488896179, COSV52383212; called by muse, varscan2
- GTF2IRD2B | c.1600T>C p.W534R | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.445); catalogued as rs1554454500; called by muse, mutect2, varscan2
- GTF3C1 | c.1502C>T p.S501F | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs1455324806, COSV62239095; called by muse, mutect2, varscan2
- GTPBP3 | c.1375G>C p.E459Q | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.773); catalogued as CM1413829, COSV61412642, COSV61414206; called by muse, mutect2, varscan2
- GUCY2F | c.3010G>A p.G1004R | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54298806; called by muse, mutect2, varscan2
- H3C2 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.648); catalogued as COSV52517721, COSV52518221; called by muse, mutect2, varscan2
- HACL1 | c.1660C>T p.L554F | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); catalogued as COSV58253580; called by muse, mutect2
- HACL1 | c.1658C>T p.S553F | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.756); catalogued as COSV58253585; called by muse, mutect2
- HDAC6 | c.2620G>T p.V874F | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.075); catalogued as COSV61927617; called by muse, mutect2, varscan2
- HEG1 | c.2275C>T p.Q759* | Nonsense Mutation (SNP) | VAF 50/210 reads (24%) | catalogued as rs769716888, COSV100231066; called by muse, mutect2, varscan2
- HEPH | c.247G>A p.D83N (on ENST00000343002; = p.D137N on NM_138737.5) | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV57959476; called by muse, mutect2, varscan2
- HFM1 | c.1894A>G p.T632A | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1202678875, COSV54021612; called by muse, mutect2, varscan2
- HGD | c.585G>C p.E195D | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.174); catalogued as COSV52196216, COSV99380699; called by muse, mutect2, varscan2
- HMCN1 | c.9166C>A p.P3056T | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54879526; called by muse, mutect2, varscan2
- HNRNPA3 | c.201G>C p.M67I | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.896); catalogued as COSV66820668; called by muse, mutect2, varscan2
- HNRNPA3 | c.326G>C p.R109T | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as COSV66820669; called by muse, mutect2, varscan2
- HORMAD1 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 22/413 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV59270361; called by muse, mutect2
- HRH4 | c.85A>G p.I29V | Missense Mutation (SNP) | VAF 40/65 reads (62%) | SIFT tolerated (0.58); PolyPhen benign (0.147); catalogued as rs1169133590, COSV56927357; called by muse, mutect2, varscan2
- HS6ST2 | c.1357A>T p.I453F | Missense Mutation (SNP) | VAF 62/78 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63710921; called by muse, mutect2, varscan2
- HTR3E | c.325G>A p.G109S (on ENST00000415389 / NM_001256613.1; = p.G124S on NM_182589.2) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.21); catalogued as COSV58945926; called by muse, mutect2, varscan2
- IFT172 | c.4187A>G p.Y1396C | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53130106; called by muse, mutect2, varscan2
- IFT172 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as COSV53130124; called by muse, mutect2, varscan2
- IGF2R | c.1586G>A p.R529Q | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as rs6413489; called by muse, mutect2, varscan2
- IKBKB | c.1518A>G p.T506= | Splice Region (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100645877; called by muse, mutect2
- IL10RB | c.583C>T p.L195F | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1157096197, COSV51614151; called by muse, mutect2, varscan2
- IL12RB2 | c.738G>A p.W246* | Nonsense Mutation (SNP) | VAF 21/60 reads (35%) | catalogued as COSV99255798; called by muse, mutect2, varscan2
- IL17RB | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV55472089, COSV99860996; called by muse, mutect2, varscan2
- IMP4 | c.683C>T p.S228L | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.3); catalogued as rs267598873, COSV52091179; called by muse, mutect2, varscan2
- INO80D | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV68957938, COSV68958175; called by muse, mutect2, varscan2
- INTS2 | c.685C>A p.L229M | Missense Mutation (SNP) | VAF 67/156 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749849092, COSV52151090; called by muse, mutect2, varscan2
- INVS | c.3121G>C p.E1041Q | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.1); catalogued as COSV52438385; called by muse, mutect2, varscan2
- IPCEF1 | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV54540833; called by muse, mutect2, varscan2
- IPO9 | c.2821G>C p.E941Q | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.046); catalogued as COSV64232846; called by muse, mutect2, varscan2
- IPO9 | c.2941G>A p.E981K | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV64232854; called by muse, mutect2, varscan2
- IQCH | c.485T>C p.V162A | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as COSV60049383; called by muse, mutect2, varscan2
- IRS1 | c.2023A>G p.I675V | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV59333695; called by muse, mutect2, varscan2
- ITGAD | c.997T>C p.Y333H | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV66756867; called by muse, mutect2, varscan2
- ITPKB | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs1435972762, COSV55257622; called by muse, mutect2, varscan2
- ITPR1 | c.8069G>T p.G2690V (on ENST00000354582; = p.G2635V on NM_002222.7) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV100233644; called by muse, mutect2
- JAG1 | c.2967G>C p.L989F | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.434); catalogued as COSV54753822; called by muse, mutect2, varscan2
- KAT6B | c.1645C>G p.H549D | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV54742623; called by muse, mutect2, varscan2
- KCNA6 | c.535G>A p.V179I | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.024); catalogued as rs781656226, COSV54974189, COSV54975172; called by muse, mutect2, varscan2
- KCNAB1 | c.280C>T p.L94F (on ENST00000490337 / NM_172160.3; = p.L83F on NM_003471.3) | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56741646; called by muse, mutect2, varscan2
- KCNC1 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV56391827; called by muse, mutect2, varscan2
- KCNG1 | c.534G>C p.E178D | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV65368006; called by muse, mutect2, varscan2
- KCNN1 | c.625T>C p.W209R | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV55837127; called by muse, mutect2, varscan2
- KCTD17 | c.934G>A p.D312N (on ENST00000403888 / NM_001282684.1; = p.D288N on NM_024681.3) | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as COSV100696221; called by muse, mutect2
- KDM5A | c.3956C>T p.S1319F | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV66990505; called by muse, mutect2, varscan2
- KDM5A | c.2395C>T p.Q799* | Nonsense Mutation (SNP) | VAF 43/143 reads (30%) | catalogued as COSV101239094; called by muse, mutect2, varscan2
- KIAA0100 | c.4630G>A p.D1544N | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.994); catalogued as COSV66490780; called by muse, mutect2, varscan2
- KIAA1210 | c.2305C>T p.Q769* | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as COSV101274456; called by muse, mutect2, varscan2
- KIAA1586 | c.1991A>G p.Y664C | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.634); catalogued as COSV66056169; called by muse, mutect2, varscan2
- KIAA1614 | c.2908G>A p.V970M | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.269); catalogued as COSV62550414; called by muse, mutect2, varscan2
- KIF1B | c.904G>C p.D302H (on ENST00000377086 / NM_001365952.1; = p.D296H on NM_015074.3) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV55803918; called by muse, mutect2, varscan2
- KIFAP3 | c.1015G>A p.D339N | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.874); catalogued as rs1386873227, COSV100810964, COSV63031196; called by muse, mutect2, varscan2
- KLHL1 | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.683); catalogued as rs753112360, COSV64766783; called by muse, mutect2, varscan2
- KMT2C | c.13178A>G p.D4393G | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.787); catalogued as COSV51318359; called by muse, mutect2, varscan2
- KNSTRN | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.085); catalogued as rs1309829547, COSV51103538; called by muse, mutect2, varscan2
- KRT10 | c.1339C>T p.Q447* | Nonsense Mutation (SNP) | VAF 25/106 reads (24%) | catalogued as COSV99510351; called by muse, mutect2, varscan2
- KRTAP10-4 | c.548C>A p.S183Y | Missense Mutation (SNP) | VAF 69/268 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.056); catalogued as COSV100555888; called by muse, varscan2
- LAMB2 | c.1618C>T p.Q540* | Nonsense Mutation (SNP) | VAF 18/82 reads (22%) | catalogued as COSV100565569; called by muse, mutect2, varscan2
- LAMTOR5 | c.73G>A p.D25N (on ENST00000602318 / NM_001382293.1; = p.D107N on NM_006402.3) | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.933); catalogued as COSV56678404; called by muse, mutect2, varscan2
- LARP7 | c.421A>T p.I141F | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV60520295; called by muse, mutect2, varscan2
- LEO1 | c.445G>T p.D149Y | Missense Mutation (SNP) | VAF 47/189 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.781); catalogued as COSV55174801; called by muse, mutect2, varscan2
- LHCGR | c.1384C>G p.L462V | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.136); catalogued as COSV54293066; called by muse, mutect2, varscan2
- LILRB1 | c.431C>T p.S144L (on ENST00000427581; = p.S108L on NM_006669.6) | Missense Mutation (SNP) | VAF 45/230 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs753911415, COSV61116144; called by muse, mutect2, varscan2
- LPIN1 | c.504G>C p.K168N | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.701); catalogued as COSV99878346; called by muse, mutect2
- LPO | c.594G>T p.K198N | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.024); catalogued as COSV51856985; called by muse, mutect2, varscan2
- LRIT2 | c.697G>C p.G233R | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV60559405, COSV60559705; called by muse, mutect2, varscan2
- LTBP1 | c.500A>C p.N167T | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63180664; called by muse, varscan2
- LY9 | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 21/457 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as rs772309907, COSV54431781; called by muse, mutect2
- MAGEB10 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as rs1241334948, COSV100775445; called by muse, mutect2, varscan2
- MAGI2 | c.3439A>G p.T1147A | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV62636092; called by muse, mutect2, varscan2
- MALT1 | c.913G>C p.E305Q | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as COSV61934136; called by muse, mutect2, varscan2
- MAP10 | c.437C>T p.S146L | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.042); catalogued as rs768882334, COSV101406533, COSV99081438; called by muse, varscan2
- MAP10 | c.2415A>T p.E805D | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.222); catalogued as COSV69362834; called by muse, mutect2, varscan2
- MAP2K2 | c.172C>G p.L58V | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.751); catalogued as COSV53562668; called by muse, mutect2, varscan2
- MAPKAPK5 | c.1073C>T p.P358L | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1418760231, COSV73436050; called by muse, mutect2, varscan2
- MATN1 | c.861G>T p.R287S | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as rs779476282, COSV65650126; called by muse, mutect2, varscan2
- MAVS | c.26A>G p.Y9C | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs749871584, COSV63926481; called by muse, mutect2, varscan2
- ME1 | c.818C>A p.T273K | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100866724; called by muse, mutect2
- MEGF8 | c.5669G>A p.G1890E (on ENST00000251268 / NM_001271938.2; = p.G1823E on NM_001410.3) | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.974); catalogued as rs772567593, COSV52076061, COSV52084693; called by muse, mutect2, varscan2
- MEIS3 | c.863C>G p.P288R (on ENST00000558555 / NM_001346148.1; = p.P334R on NM_020160.3) | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV58982892; called by muse, mutect2, varscan2
- MET | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs561295443, COSV59257220, COSV59260500; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- METTL24 | c.786+2T>A p.X262_splice | Splice Site (SNP) | VAF 21/52 reads (40%) | catalogued as COSV58821077; called by muse, mutect2, varscan2
- MFSD11 | c.653A>G p.N218S | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1489961879, COSV60620867; called by muse, mutect2, varscan2
- MGME1 | c.9G>A p.M3I | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV66623901; called by muse, mutect2, varscan2
- MIA3 | c.4658C>T p.S1553L | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as COSV60510134; called by muse, mutect2, varscan2
- MINDY1 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 25/231 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.018); catalogued as COSV56497741; called by muse, mutect2, varscan2
- MIOS | c.1882C>G p.Q628E | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV60767132; called by muse, mutect2, varscan2
- MISP | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV53118926; called by muse, mutect2, varscan2
- MME | c.1842C>G p.N614K | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.505); catalogued as COSV64706098; called by muse, mutect2, varscan2
- MMP1 | c.524A>T p.D175V | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59509453; called by muse, varscan2
- MMP16 | c.1570T>C p.S524P | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54152233; called by muse, mutect2, varscan2
- MMP9 | c.692A>C p.H231P | Missense Mutation (SNP) | VAF 61/190 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63433789; called by muse, mutect2, varscan2
- MMS22L | c.2644G>A p.E882K | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.053); catalogued as rs746053321, COSV51516955; called by muse, mutect2, varscan2
- MMUT | c.586C>T p.L196F | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV51272369; called by muse, mutect2, varscan2
- MRPL53 | c.49C>T p.R17W | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.676); catalogued as rs758633639, COSV50688336; called by muse, mutect2, varscan2
- MSI2 | c.749G>A p.G250E | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); catalogued as COSV52353473; called by muse, mutect2, varscan2
- MUC16 | c.31861G>T p.E10621* | Nonsense Mutation (SNP) | VAF 15/97 reads (15%) | catalogued as COSV101202158; called by muse, mutect2, varscan2
- MUC16 | c.2925G>T p.K975N | Missense Mutation (SNP) | VAF 117/258 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV67447176; called by muse, mutect2, varscan2
- MVB12A | c.781G>C p.E261Q | Missense Mutation (SNP) | VAF 42/237 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57678397; called by muse, mutect2, varscan2
- MYH13 | c.3691G>A p.E1231K | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV52821455; called by muse, mutect2, varscan2
- MYO18B | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs751222865, COSV59126310, COSV59129122; called by muse, mutect2, varscan2
- MYO3A | c.3694A>C p.K1232Q | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.009); catalogued as COSV56320733, COSV56323907; called by muse, mutect2, varscan2
- NCAPG2 | c.3430T>G p.*1144Eext*14 | Nonstop Mutation (SNP) | VAF 18/69 reads (26%) | catalogued as COSV99317717; called by muse, mutect2, varscan2
- NDE1 | c.978G>C p.E326D (on ENST00000577101; = p.D299H on NM_017668.3) | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV61270362; called by muse, mutect2, varscan2
- NEB | c.4264G>A p.E1422K | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.992); catalogued as COSV50817243, COSV51423602; called by muse, mutect2, varscan2
- NEBL | c.1700T>C p.M567T | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.81); PolyPhen benign (0.05); catalogued as COSV65801521; called by muse, mutect2, varscan2
- NEK11 | c.1292A>T p.D431V | Missense Mutation (SNP) | VAF 36/210 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.058); catalogued as rs1454507772, COSV63578824; called by muse, mutect2, varscan2
- NEU1 | c.934G>C p.E312Q | Missense Mutation (SNP) | VAF 56/88 reads (64%) | SIFT tolerated (0.11); PolyPhen benign (0.082); catalogued as COSV57665874; called by muse, mutect2, varscan2
- NFXL1 | c.1010G>C p.R337T | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV61198118; called by muse, mutect2, varscan2
- NGLY1 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99771007; called by muse, mutect2
- NKTR | c.3151A>G p.I1051V | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs368548741; called by muse, mutect2, varscan2
- NKX2-5 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.112); catalogued as rs1365219269, COSV61298358; called by muse, mutect2, varscan2
- NLRC5 | c.1772A>T p.K591M | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV52649719; called by muse, mutect2, varscan2
- NOC3L | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.165); catalogued as COSV64929634; called by muse, mutect2, varscan2
- NOL6 | c.511T>C p.C171R | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs767604471, COSV53039432; called by muse, mutect2, varscan2
- NPY5R | c.1106G>A p.R369K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.031); catalogued as COSV58451080, COSV58451188, COSV58453297; called by muse, mutect2, varscan2
- NRSN1 | c.209C>T p.T70I | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.013); catalogued as COSV65893703; called by muse, mutect2, varscan2
- NSMAF | c.536G>A p.R179K | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.46); catalogued as COSV50684057; called by muse, mutect2, varscan2
- NSMCE1 | c.309G>C p.E103D | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.039); catalogued as COSV63863848; called by muse, mutect2, varscan2
- NT5E | c.554C>G p.S185* | Nonsense Mutation (SNP) | VAF 14/37 reads (38%) | catalogued as COSV100004432; called by muse, mutect2, varscan2
- NUS1 | c.790G>T p.V264F | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as COSV63843881; called by muse, mutect2, varscan2
- OGG1 | c.452A>G p.N151S | Missense Mutation (SNP) | VAF 38/172 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as rs764308935, COSV57351450; called by muse, mutect2, varscan2
- OLFM2 | c.232T>C p.S78P | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53428731; called by muse, mutect2, varscan2
- OPN4 | c.919C>T p.L307F | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as COSV54114860; called by muse, mutect2, varscan2
- OR10J3 | c.268C>T p.H90Y | Missense Mutation (SNP) | VAF 16/400 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV59953682; called by muse, mutect2
- OR10J5 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 22/436 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as rs1429840609, COSV58384950; called by muse, mutect2
- OR4C16 | c.422T>G p.V141G | Missense Mutation (SNP) | VAF 51/167 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.616); catalogued as COSV58940871; called by muse, mutect2, varscan2
- OR8B2 | c.752T>A p.F251Y | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.457); catalogued as COSV100899530; called by muse, mutect2, varscan2
- OSMR | c.1957C>G p.Q653E | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV57081288; called by muse, mutect2, varscan2
- OTOGL | c.4948A>G p.T1650A (on ENST00000547103; = p.T1641A on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as rs770277934, COSV54013521; called by muse, mutect2, varscan2
- P2RX3 | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54441543; called by muse, mutect2, varscan2
- P3H2 | c.610G>C p.D204H | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60018648; called by muse, mutect2, varscan2
- PABPC1 | c.1121G>A p.R374H | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59398825; called by muse, mutect2, varscan2
- PACSIN3 | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.381); catalogued as COSV54065242; called by muse, mutect2, varscan2
- PANK3 | c.448G>T p.D150Y | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as rs1268304539, COSV53321956; called by muse, mutect2, varscan2
- PANX2 | c.523A>G p.K175E | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.688); catalogued as COSV99348742; called by muse, mutect2
- PAX7 | c.1240G>A p.D414N | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.146); catalogued as COSV64748651; called by muse, mutect2, varscan2
- PAXIP1 | c.751G>A p.D251N | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as COSV101250167; called by muse, mutect2
- PBX3 | c.727A>G p.S243G | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.236); catalogued as rs1464870108, COSV60730235, COSV60730644; called by muse, mutect2, varscan2
- PCARE | c.3481G>A p.E1161K | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as COSV100527680, COSV59053209; called by muse, mutect2, varscan2
- PCDH8 | c.163A>G p.M55V | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.013); catalogued as rs984931630, COSV58810949; called by muse, mutect2, varscan2
- PCDHAC1 | c.2717C>T p.S906F | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53838187; called by muse, mutect2, varscan2
- PCDHGA1 | c.860G>C p.R287T | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); catalogued as COSV65295125; called by muse, mutect2, varscan2
- PCDHGA8 | c.563G>C p.G188A | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); catalogued as rs749009041, COSV53903990; called by muse, mutect2, varscan2
- PCDHGC4 | c.1793T>A p.L598* | Nonsense Mutation (SNP) | VAF 22/69 reads (32%) | catalogued as COSV99342891; called by muse, mutect2, varscan2
- PFKM | c.1918A>G p.I640V | Missense Mutation (SNP) | VAF 46/175 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.711); catalogued as rs142495522; called by muse, mutect2, varscan2
- PHACTR4 | c.1719G>T p.E573D (on ENST00000373839 / NM_001350159.2; = p.E583D on NM_023923.4) | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV65783197; called by muse, mutect2, varscan2
- PHIP | c.1858C>T p.Q620* | Nonsense Mutation (SNP) | VAF 15/24 reads (63%) | catalogued as COSV99245115; called by muse, mutect2, varscan2
- PHKA1 | c.173G>A p.G58D | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV100264058; called by muse, mutect2, varscan2
- PHKB | c.1889G>A p.R630Q | Missense Mutation (SNP) | VAF 37/61 reads (61%) | SIFT tolerated (0.53); PolyPhen benign (0.183); catalogued as rs771531628, COSV54515097; called by muse, mutect2, varscan2
- PHRF1 | c.460T>A p.C154S | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV52751429, COSV99199579; called by muse, mutect2, varscan2
- PI4KA | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV55405112; called by muse, mutect2, varscan2
- PI4KB | c.329C>G p.S110* (on ENST00000368873 / NM_001369623.1; = p.S122* on NM_002651.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 39/288 reads (14%) | catalogued as COSV55020541, COSV99650326; called by muse, mutect2, varscan2
- PKD1 | c.8953A>G p.R2985G | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs373952574, CM014075, COSV51911221; called by muse, mutect2, varscan2
- PKHD1 | c.5180C>T p.S1727L | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); catalogued as rs1344717858, COSV61862149; called by muse, mutect2, varscan2
- PKM | c.1219G>C p.D407H | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV100065351, COSV58788410; called by muse, mutect2, varscan2
- PLEK | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.994); catalogued as COSV52250692; called by muse, mutect2, varscan2
- PLXNA1 | c.3404C>A p.S1135Y | Missense Mutation (SNP) | VAF 54/242 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV52522594; called by muse, mutect2, varscan2
- PMM1 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.179); catalogued as rs964162207, COSV53447144; called by muse, mutect2, varscan2
- PNRC1 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.13); catalogued as COSV60139057, COSV60140599; called by muse, mutect2
- POGLUT2 | c.829C>G p.L277V | Missense Mutation (SNP) | VAF 103/295 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs368149831; called by muse, mutect2, varscan2
- POLQ | c.1817G>C p.G606A | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.013); catalogued as COSV51746468; called by muse, mutect2, varscan2
- PON3 | c.569T>A p.L190Q | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55698016; called by muse, mutect2, varscan2
- PPIL4 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.433); catalogued as COSV99481984; called by muse, mutect2
- PPM1E | c.535T>C p.S179P | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs769566644, COSV57571207; called by muse, mutect2, varscan2
- PPP5C | c.1429A>T p.T477S | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV50139271; called by muse, mutect2, varscan2
- PPRC1 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs753734181, COSV53383374; called by muse, mutect2, varscan2
- PRCP | c.1084C>G p.Q362E | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57287623; called by muse, mutect2, varscan2
- PRDM4 | c.388A>G p.I130V | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs1312830539, COSV57304673; called by muse, mutect2, varscan2
- PRDM5 | c.544C>G p.L182V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53356299, COSV99311393; called by muse, mutect2, varscan2
- PRKCB | c.296G>T p.R99L | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as COSV57767165, COSV57769485; called by muse, mutect2, varscan2
- PRPF3 | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 40/490 reads (8%) | catalogued as COSV100255192; called by muse, mutect2
- PRPS1L1 | c.94A>G p.T32A | Missense Mutation (SNP) | VAF 41/192 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV72649821; called by muse, mutect2, varscan2
- PSD2 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs761796726, COSV51197205; called by muse, mutect2, varscan2
- PSORS1C1 | c.165C>T p.F55= | Splice Region (SNP) | VAF 132/216 reads (61%) | catalogued as COSV52535115; called by muse, mutect2, varscan2
- PTCH1 | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.511); catalogued as COSV59461287; called by muse, mutect2, varscan2
- PTPRA | c.251C>G p.S84C | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.188); catalogued as COSV53778654; called by muse, mutect2, varscan2
- PTPRF | c.4172G>C p.R1391P | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as COSV63442739, COSV63444222; called by muse, mutect2, varscan2
- PTPRO | c.623A>G p.Y208C | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV55503948; called by muse, mutect2, varscan2
- PXDNL | c.3781G>A p.G1261S | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.646); catalogued as COSV62479293; called by muse, mutect2, varscan2
- PYCARD | c.86C>A p.S29* | Nonsense Mutation (SNP) | VAF 12/93 reads (13%) | catalogued as rs1387481310, COSV99910988; called by muse, mutect2, varscan2
- PYDC1 | c.183C>G p.Y61* | Nonsense Mutation (SNP) | VAF 16/105 reads (15%) | catalogued as COSV100265496, COSV57252435; called by muse, mutect2, varscan2
- PYGO2 | c.1121C>T p.S374F | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV63756643; called by muse, mutect2, varscan2
- RAB3IP | c.1226A>T p.K409I (on ENST00000550536 / NM_175623.4; = p.K393I on NM_022456.5) | Missense Mutation (SNP) | VAF 361/399 reads (90%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV56081785, COSV56081929; called by muse, mutect2, varscan2
- RAB8A | c.67T>C p.C23R | Missense Mutation (SNP) | VAF 48/220 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56290989; called by muse, mutect2, varscan2
- RABEP2 | c.1682C>G p.T561R | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as COSV62868581; called by muse, mutect2
- RAD9A | c.143A>G p.Y48C | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs763818008, COSV57236122; called by muse, mutect2, varscan2
- RARG | c.835T>C p.Y279H | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as COSV58432036; called by muse, mutect2, varscan2
- RASGEF1C | c.211C>G p.R71G | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV63177705, COSV63186250; called by muse, mutect2, varscan2
- RBM14 | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV59557932; called by muse, mutect2, varscan2
- RBM23 | c.1085C>T p.S362L (on ENST00000359890 / NM_001077351.2; = p.S346L on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV57126942; called by muse, mutect2, varscan2
- RBM43 | c.289C>T p.L97F | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.01); catalogued as COSV58878172; called by muse, mutect2, varscan2
- REL | c.1497G>A p.M499I | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as COSV54362453; called by muse, mutect2, varscan2
- REXO1 | c.616G>A p.V206M | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as COSV99402719; called by muse, mutect2, varscan2
- RGL3 | c.389C>A p.T130K | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.312); catalogued as COSV62697248; called by muse, mutect2, varscan2
- RGR | c.686G>A p.G229D | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV63893417; called by muse, mutect2, varscan2
- RHBG | c.1043C>T p.P348L | Missense Mutation (SNP) | VAF 35/170 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs202077403, COSV54802009; called by muse, mutect2, varscan2
- RHEB | c.169C>T p.Q57* | Nonsense Mutation (SNP) | VAF 16/42 reads (38%) | catalogued as COSV51263010; called by muse, mutect2, varscan2
- RIC1 | c.4204G>A p.E1402K | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs767256306, COSV52605347; called by muse, mutect2, varscan2
- RLIM | c.1656G>C p.Q552H | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100223036, COSV60325355; called by muse, mutect2, varscan2
- RLN1 | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 74/141 reads (52%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV56346156; called by muse, mutect2, varscan2
- RNF144A | c.133C>T p.L45= | Splice Region (SNP) | VAF 23/113 reads (20%) | catalogued as COSV57980505; called by muse, mutect2, varscan2
- RNF17 | c.3010C>G p.L1004V | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV55034601; called by muse, mutect2, varscan2
- RNF213 | c.2630G>A p.R877K | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT tolerated (0.76); PolyPhen benign (0.031); catalogued as COSV60619181; called by muse, mutect2, varscan2
- RNF213 | c.9784G>A p.A3262T | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as rs759888992, COSV60391048; called by muse, mutect2, varscan2
- RNF40 | c.2918G>T p.R973L | Missense Mutation (SNP) | VAF 7/183 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as COSV52697518, COSV52697820; called by muse, mutect2
- RPGR | c.2471G>C p.R824T (on ENST00000339363 / NM_001367249.1; = p.R619T on NM_000328.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.074); catalogued as COSV58832664; called by muse, mutect2, varscan2
- RPS19 | c.376C>T p.Q126* | Nonsense Mutation (SNP) | VAF 8/57 reads (14%) | catalogued as CM077624, COSV55743988; called by muse, mutect2, varscan2
- RPS6KA6 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.023); catalogued as COSV53116517; called by muse, mutect2, varscan2
- RRM2B | c.740C>T p.S247L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.073); catalogued as COSV52565693; called by muse, mutect2, varscan2
- RSPH10B | c.726G>A p.M242I | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1308840868, COSV100521456; called by muse, mutect2
- RSPH4A | c.535G>C p.D179H | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as COSV57633737, COSV57635282; called by muse, mutect2, varscan2
- RTCA | c.368G>T p.G123V | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1005876725, COSV53119503; called by muse, mutect2, varscan2
- RUSC1 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.041); catalogued as COSV52738319; called by muse, mutect2, varscan2
- RWDD1 | c.462G>A p.W154* | Nonsense Mutation (SNP) | VAF 7/49 reads (14%) | catalogued as rs1241534636, COSV63972538; called by muse, mutect2, varscan2
- RYR2 | c.1439G>A p.R480Q | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as COSV100771998, COSV63674220; called by muse, mutect2
- SBF1 | c.5597G>A p.R1866H | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as rs770090328, COSV53290435; called by muse, mutect2, varscan2
- SCNM1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99766266; called by muse, mutect2
- SEMA3E | c.38G>T p.W13L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV57080586; called by muse, mutect2, varscan2
- SEMA4A | c.1520T>C p.V507A | Missense Mutation (SNP) | VAF 171/378 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as COSV61772116; called by muse, mutect2, varscan2
- SEPHS1 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 100/457 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV59257243, COSV59260027; called by muse, mutect2, varscan2
- SESN1 | c.1129G>A p.E377K (on ENST00000356644 / NM_001199933.1; = p.E436K on NM_014454.3) | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV57420303; called by muse, mutect2, varscan2
- SETD4 | c.1129G>T p.D377Y | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV59771284; called by muse, mutect2, varscan2
- SETX | c.5524C>T p.H1842Y | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV56379487; called by muse, mutect2, varscan2
- SHROOM3 | c.5249A>G p.Y1750C | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56023702; called by muse, mutect2, varscan2
- SIGLEC5 | c.1577C>G p.S526C | Missense Mutation (SNP) | VAF 77/135 reads (57%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.473); catalogued as COSV55777679, COSV55783708; called by muse, mutect2, varscan2
- SIRT3 | c.481G>A p.G161R | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV61500414; called by muse, mutect2, varscan2
- SKOR1 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100408355, COSV58244028; called by muse, mutect2, varscan2
- SLC10A5 | c.1285C>A p.Q429K | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV72828265; called by muse, mutect2, varscan2
- SLC12A9 | c.1050C>G p.I350M | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV51931478; called by muse, mutect2, varscan2
- SLC15A2 | c.1465C>G p.L489V | Missense Mutation (SNP) | VAF 21/204 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as rs1480128603, COSV55196153; called by muse, mutect2, varscan2
- SLC38A3 | c.341T>C p.I114T | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV101310018; called by muse, mutect2, varscan2
- SLC39A6 | c.2038C>T p.H680Y | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV52367853; called by muse, mutect2, varscan2
- SLC5A1 | c.1837G>C p.E613Q | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.019); catalogued as rs199692197, COSV56683506; called by muse, mutect2, varscan2
- SLC8A2 | c.259T>A p.S87T | Missense Mutation (SNP) | VAF 56/141 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52637965; called by muse, mutect2, varscan2
- SLFN5 | c.810G>C p.Q270H | Missense Mutation (SNP) | VAF 38/179 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as COSV55479891; called by muse, mutect2, varscan2
- SLITRK3 | c.2443G>C p.E815Q | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as COSV53845848, COSV53847718; called by muse, mutect2, varscan2
- SMARCA2 | c.295A>G p.M99V | Missense Mutation (SNP) | VAF 97/191 reads (51%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.183); catalogued as rs1026030682, COSV61804968; called by muse, mutect2, varscan2
- SMC2 | c.2740G>A p.D914N | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as COSV53955215; called by muse, mutect2, varscan2
- SMC5 | c.3058G>C p.E1020Q | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100747143, COSV63191732; called by muse, mutect2, varscan2
- SNAP91 | c.2011G>T p.A671S | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.031); catalogued as COSV99536956; called by muse, mutect2
- SNX17 | c.1113G>A p.M371I | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs1558307204, COSV52006546; called by muse, mutect2, varscan2
- SORCS3 | c.2209T>G p.S737A | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.023); catalogued as COSV63793574; called by muse, mutect2, varscan2
- SOS1 | c.2092G>A p.E698K | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.47); catalogued as COSV67673973, COSV67674055; called by muse, mutect2, varscan2
- SOX8 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV53508807; called by muse, mutect2, varscan2
- SPAG5 | c.2403G>C p.E801D | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58800201, COSV58801732; called by muse, mutect2, varscan2
- SPANXB1 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 50/446 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as rs1263884495; called by muse, varscan2
- SPATA46 | c.139A>G p.S47G | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.164); catalogued as COSV62632269; called by muse, mutect2, varscan2
- SPATA7 | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50416019; called by muse, mutect2, varscan2
- SPDYC | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as rs375713923; called by muse, mutect2, varscan2
- SPHK2 | c.1117C>T p.R373C | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs868065313, COSV55335051; called by muse, mutect2, varscan2
- SPTA1 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as COSV63749343; called by muse, mutect2, varscan2
- SPTBN4 | c.5547G>C p.Q1849H | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV58944019; called by muse, mutect2, varscan2
- SSBP3 | c.669G>A p.M223I (on ENST00000371320 / NM_145716.4; = p.M203I on NM_018070.5) | Missense Mutation (SNP) | VAF 47/173 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.588); catalogued as rs1462775667, COSV58884721; called by muse, mutect2, varscan2
- SSTR4 | c.590C>A p.A197D | Missense Mutation (SNP) | VAF 84/143 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs1296956248, COSV54797056; called by muse, mutect2, varscan2
- ST13 | c.114G>C p.M38I | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.107); catalogued as COSV53420874; called by muse, mutect2, varscan2
- STIL | c.1862A>G p.Q621R | Missense Mutation (SNP) | VAF 49/151 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV54547831; called by muse, mutect2, varscan2
- STPG2 | c.452A>T p.E151V | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as COSV54786652; called by muse, mutect2, varscan2
- STX12 | c.141G>A p.M47I | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs1401939693, COSV64248954; called by muse, mutect2, varscan2
- SULF2 | c.1903-1G>A p.X635_splice | Splice Site (SNP) | VAF 43/153 reads (28%) | catalogued as COSV63413797, COSV63414102; called by muse, mutect2, varscan2
- SULT1B1 | c.146C>G p.S49* | Nonsense Mutation (SNP) | VAF 28/80 reads (35%) | catalogued as COSV100150521; called by muse, mutect2, varscan2
- SUPT6H | c.344G>C p.G115A | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV58924782, COSV58928348; called by muse, mutect2, varscan2
- SWT1 | c.1437G>C p.L479F | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.219); catalogued as COSV62253026; called by muse, mutect2, varscan2
- SYNE1 | c.5910G>C p.Q1970H (on ENST00000367255 / NM_182961.4; = p.Q1977H on NM_033071.3) | Missense Mutation (SNP) | VAF 54/226 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54914517; called by muse, mutect2, varscan2
- TAAR8 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 53/266 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs1433950837, COSV51585633; called by muse, mutect2, varscan2
- TACC2 | c.1685C>T p.P562L | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV57747157; called by muse, mutect2, varscan2
- TAF11 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 56/173 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as COSV63542820; called by muse, mutect2, varscan2
- TAF15 | c.1685G>A p.R562Q (on ENST00000605844 / NM_139215.3; = p.R559Q on NM_003487.4) | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs752394270; called by muse, mutect2, varscan2
- TAS2R46 | c.896A>T p.Y299F | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV67852873; called by muse, varscan2
- TCHH | c.1271A>G p.Q424R | Missense Mutation (SNP) | VAF 20/154 reads (13%) | PolyPhen benign (0.003); catalogued as COSV64273126; called by muse, varscan2
- TCHHL1 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 36/532 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV64284932; called by muse, mutect2
- TCHP | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs140118187; called by muse, mutect2, varscan2
- TCN1 | c.1190A>G p.N397S | Missense Mutation (SNP) | VAF 63/175 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as COSV57252176; called by muse, mutect2, varscan2
- TCTN2 | c.25C>G p.L9V | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as COSV57635322; called by muse, mutect2
- TDRD3 | c.1178C>T p.P393L | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs776432685, COSV52153351; called by muse, mutect2, varscan2
- TENT2 | c.468G>A p.L156= | Splice Region (SNP) | VAF 7/22 reads (32%) | catalogued as rs747930740, COSV57134737; called by muse, mutect2, varscan2
- TEX44 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as COSV58354631; called by muse, mutect2
- TEX45 | c.1140G>T p.E380D | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV64462727; called by muse, mutect2, varscan2
- TEX47 | c.387G>A p.M129I | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.76); PolyPhen benign (0.075); catalogued as rs867402496, COSV51878249; called by muse, mutect2, varscan2
- TF | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748119838, COSV53917789; called by muse, mutect2, varscan2
- THAP9 | c.114G>C p.W38C | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56355737; called by muse, mutect2, varscan2
- THPO | c.493C>T p.P165S (on ENST00000649095 / NM_001290003.1; = p.P25S on NM_000460.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV52605726; called by muse, mutect2, varscan2
- TJP2 | c.1223T>C p.I408T | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV55262831; called by muse, mutect2, varscan2
- TKTL2 | c.361G>C p.V121L | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as rs774381017, COSV54917496, COSV54918618; called by muse, mutect2, varscan2
- TLR8 | c.1189T>C p.S397P (on ENST00000218032 / NM_138636.5; = p.S415P on NM_016610.4) | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.124); catalogued as COSV54316556; called by muse, mutect2, varscan2
- TMEM117 | c.364T>G p.F122V | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.115); catalogued as COSV56895400; called by muse, mutect2, varscan2
- TMEM67 | c.1831A>T p.T611S | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.013); catalogued as COSV60036206; called by muse, mutect2
- TMEM79 | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 18/75 reads (24%) | catalogued as COSV99828193; called by muse, mutect2, varscan2
- TMPRSS4 | c.766T>C p.W256R | Missense Mutation (SNP) | VAF 80/171 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV71108428; called by muse, mutect2, varscan2
- TMPRSS7 | c.1810C>G p.H604D (on ENST00000452346; = p.H478D on NM_001042575.2) | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0.01); catalogued as COSV69979631, COSV69979639; called by muse, mutect2, varscan2
- TNFAIP6 | c.742G>C p.D248H | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.21); catalogued as COSV54640010; called by muse, mutect2, varscan2
- TNRC18 | c.1558G>A p.A520T | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1433422962, COSV101259537; called by muse, mutect2, varscan2
- TOPBP1 | c.696A>T p.Q232H | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as COSV53432619; called by muse, mutect2, varscan2
- TP53BP2 | c.3142C>T p.Q1048* (on ENST00000343537 / NM_001031685.3; = p.Q919* on NM_005426.2) | Nonsense Mutation (SNP) | VAF 46/109 reads (42%) | catalogued as COSV100636868; called by muse, mutect2, varscan2
- TPSD1 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.75); PolyPhen benign (0.181); catalogued as COSV52974067; called by muse, mutect2, varscan2
- TRARG1 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.68); PolyPhen benign (0.158); catalogued as rs751171532, COSV61562502, COSV61563020; called by muse, mutect2, varscan2
- TREM1 | c.184G>C p.E62Q | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV55147861; called by muse, mutect2, varscan2
- TRIM56 | c.181G>C p.E61Q | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.373); catalogued as COSV60157320, COSV60158785, COSV60161251; called by muse, mutect2, varscan2
- TRMT2A | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs777596749, COSV52812455; called by muse, mutect2, varscan2
- TRPC6 | c.2403G>A p.M801I | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV60251166, COSV60259639; called by muse, mutect2, varscan2
- TRRAP | c.7710G>C p.Q2570H (on ENST00000359863 / NM_001244580.1; = p.Q2552H on NM_003496.3) | Missense Mutation (SNP) | VAF 66/206 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.122); catalogued as COSV62839535; called by muse, mutect2, varscan2
- TSSK3 | c.56G>C p.G19A | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61981334; called by muse, mutect2, varscan2
- TTC13 | c.658G>C p.E220Q | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.34); catalogued as COSV64167813; called by muse, mutect2, varscan2
- TTC17 | c.2284G>A p.E762K | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.202); catalogued as COSV50006181; called by muse, mutect2, varscan2
- TTC38 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66843622; called by muse, mutect2, varscan2
- TTC7B | c.1547A>G p.Q516R | Missense Mutation (SNP) | VAF 40/64 reads (63%) | SIFT tolerated (0.29); PolyPhen benign (0.057); catalogued as COSV60625607; called by muse, mutect2, varscan2
- TTI2 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as COSV62452117; called by muse, mutect2, varscan2
- TTN | c.85627G>A p.E28543K (on ENST00000591111; = p.E21119K on NM_003319.4) | Missense Mutation (SNP) | VAF 16/36 reads (44%) | PolyPhen possibly damaging (0.736); catalogued as COSV59902539; called by muse, mutect2, varscan2
- TTN | c.67328C>G p.S22443C (on ENST00000591111; = p.S15019C on NM_003319.4) | Missense Mutation (SNP) | VAF 23/46 reads (50%) | PolyPhen probably damaging (0.912); catalogued as COSV59902556; called by muse, mutect2, varscan2
- TTPA | c.663G>C p.R221= | Splice Region (SNP) | VAF 9/27 reads (33%) | catalogued as COSV99478663; called by muse, mutect2
- TUBB4B | c.282G>C p.Q94H | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.013); catalogued as COSV61115579; called by muse, mutect2, varscan2
- TXLNA | c.537G>C p.L179F | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV65313889; called by muse, mutect2, varscan2
- TYRO3 | c.1453C>G p.R485G | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776839937, COSV55480998, COSV55483604; called by muse, mutect2, varscan2
- UBAP2L | c.2612C>T p.S871F | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV55168142, COSV55179870; called by muse, mutect2, varscan2
- UBE2H | c.505T>G p.S169A | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.097); catalogued as COSV62919832; called by muse, mutect2, varscan2
- UBR2 | c.297T>A p.C99* | Nonsense Mutation (SNP) | VAF 15/83 reads (18%) | catalogued as COSV100868760; called by muse, mutect2, varscan2
- UCK1 | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 24/123 reads (20%) | catalogued as COSV100944143; called by muse, varscan2
- UGT1A1 | c.1170G>A p.M390I | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); catalogued as rs1559415443, COSV59382744; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UNC13A | c.2542G>A p.D848N | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV53188963; called by muse, mutect2, varscan2
- UNC13D | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.421); catalogued as COSV52883143; called by muse, mutect2, varscan2
- UQCRC1 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV52550934; called by muse, mutect2, varscan2
- USH2A | c.15424C>T p.H5142Y | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV56331598; called by muse, mutect2, varscan2
- USH2A | c.15227G>C p.R5076T | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56331616, COSV56370180; called by muse, mutect2, varscan2
- USP9Y | c.5901G>A p.M1967I | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV59098729, COSV59100065; called by muse, mutect2, varscan2
- VMP1 | c.190A>G p.I64V | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1401772737, COSV51864872; called by muse, mutect2, varscan2
- VPREB1 | c.73C>G p.Q25E | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs934910151, COSV56425358; called by muse, mutect2, varscan2
- VPS13B | c.5503A>G p.I1835V | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.219); catalogued as rs1197351465, COSV62134065; called by muse, mutect2, varscan2
- VPS35L | c.2448G>C p.E816D | Missense Mutation (SNP) | VAF 39/196 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV51977570; called by muse, mutect2, varscan2
- WDR33 | c.3530G>A p.R1177Q | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as rs765816436, COSV59246374; called by muse, mutect2, varscan2
- WNK1 | c.4593G>C p.K1531N (on ENST00000315939 / NM_018979.4; = p.K1284N on NM_014823.3) | Missense Mutation (SNP) | VAF 84/398 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV60026265, COSV60040947; called by muse, mutect2, varscan2
- WRAP73 | c.380C>G p.S127C | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV54560110; called by muse, mutect2, varscan2
- YPEL5 | c.295G>A p.V99M | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1161394088, COSV54394856; called by muse, mutect2, varscan2
- ZAN | c.7984C>G p.Q2662E | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.737); catalogued as rs1187741761, COSV61805481; called by muse, mutect2, varscan2
- ZBTB47 | c.1846A>G p.K616E | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51763605; called by muse, mutect2
- ZDHHC21 | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 31/193 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs1258062053, COSV66612261; called by muse, mutect2, varscan2
- ZGPAT | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1427831274, COSV60831145; called by muse, mutect2, varscan2
- ZMYM5 | c.1758T>G p.D586E | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV61987392; called by muse, mutect2, varscan2
- ZNF148 | c.2351C>T p.S784L | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as rs1443402387, COSV62302440; called by muse, mutect2, varscan2
- ZNF148 | c.1313C>T p.S438L | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV62302448; called by muse, mutect2, varscan2
- ZNF276 | c.1238C>A p.P413Q (on ENST00000443381 / NM_001113525.2; = p.P338Q on NM_152287.4) | Missense Mutation (SNP) | VAF 89/133 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs771486347, COSV57066068, COSV57071528; called by muse, mutect2, varscan2
- ZNF292 | c.1683G>C p.Q561H | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60535962; called by muse, mutect2, varscan2
- ZNF318 | c.5197C>T p.P1733S | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.028); catalogued as rs753512081, COSV58930405; called by muse, mutect2, varscan2
- ZNF37A | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV61072595; called by muse, mutect2, varscan2
- ZNF471 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.039); catalogued as COSV57289964; called by muse, mutect2, varscan2
- ZNF536 | c.1225C>T p.P409S | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as COSV62819090; called by muse, mutect2, varscan2
- ZNF589 | c.683C>T p.S228L | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.437); catalogued as COSV61220116; called by muse, mutect2, varscan2
- ZNF630 | c.1764A>G p.I588M | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV52095041; called by muse, mutect2, varscan2
- ZNF638 | c.1873G>A p.A625T | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs202139397, COSV52482379; called by muse, mutect2, varscan2
- ZNF791 | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as COSV100588983; called by muse, mutect2, varscan2
- ZNF836 | c.250G>C p.E84Q | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.932); catalogued as COSV59081237; called by muse, mutect2, varscan2
- ATF2 | c.1292-13_1308del p.X431_splice | Splice Site (DEL) | VAF 14/60 reads (23%) | called by mutect2, pindel
- CABIN1 | c.2367del p.Q789Hfs*3 | Frame Shift Del (DEL) | VAF 14/49 reads (29%) | called by mutect2, pindel, varscan2
- CSMD2 | c.1491_1500del p.F498Mfs*198 | Frame Shift Del (DEL) | VAF 16/78 reads (21%) | called by mutect2, pindel, varscan2
- DENND6A | c.688del p.V230Wfs*2 | Frame Shift Del (DEL) | VAF 12/59 reads (20%) | called by mutect2, pindel, varscan2
- GPR89B | c.224G>A p.W75* | Nonsense Mutation (SNP) | VAF 31/565 reads (5%) | called by muse, mutect2
- HNF1B | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGHV1-18 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 113/154 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- NAV2 | c.6188_6189del p.K2063Rfs*69 (on ENST00000396087 / NM_001244963.2; = p.K2004Rfs*69 on NM_145117.5) | Frame Shift Del (DEL) | VAF 40/148 reads (27%) | called by mutect2, pindel, varscan2
- NAV3 | c.2458_2464del p.Y820Vfs*20 | Frame Shift Del (DEL) | VAF 22/55 reads (40%) | called by mutect2, pindel, varscan2
- OBSCN | c.6810_6814del p.Q2271Cfs*68 | Frame Shift Del (DEL) | VAF 31/81 reads (38%) | called by mutect2, pindel, varscan2
- SRRM2 | c.5846_5852delinsCT p.R1949Tfs*69 | Frame Shift Del (DEL) | VAF 17/61 reads (28%) | called by pindel, varscan2*
- STAM2 | c.918_935del p.S306_S312delinsR | In Frame Del (DEL) | VAF 7/46 reads (15%) | called by mutect2, pindel, varscan2
- TIAM1 | c.2980_2991+6del p.X994_splice | Splice Site (DEL) | VAF 6/47 reads (13%) | called by mutect2, pindel
- TRAV8-4 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 72/142 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- USH2A | c.12619del p.A4207Pfs*50 | Frame Shift Del (DEL) | VAF 17/116 reads (15%) | called by mutect2, pindel, varscan2
- VAPB | c.717del p.K240Rfs*28 | Frame Shift Del (DEL) | VAF 25/114 reads (22%) | called by mutect2, pindel, varscan2
- VIM | c.1133_1138del p.R378_H379del | In Frame Del (DEL) | VAF 21/111 reads (19%) | called by mutect2, pindel, varscan2
- ZNF546 | c.825dup p.K276* | Frame Shift Ins (INS) | VAF 16/62 reads (26%) | called by mutect2, pindel, varscan2
- ABCC6 | c.3228C>T p.V1076= | Silent (SNP) | VAF 18/138 reads (13%) | catalogued as COSV52742131; called by mutect2, varscan2
- ACSS2 | c.1395C>T p.F465= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as COSV53622807; called by muse, mutect2, varscan2
- ACTRT3 | c.105C>T p.I35= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as rs947447057, COSV57753812; called by muse, mutect2, varscan2
- ADAM23 | c.1134C>T p.R378= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV52208264; called by muse, mutect2, varscan2
- ADGRD1 | c.2307G>C p.L769= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV55439536; called by muse, mutect2, varscan2
- ADGRV1 | c.18090T>A p.V6030= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV67979101; called by muse, mutect2, varscan2
- AK2 | c.342C>T p.F114= (on ENST00000354858; = p.F156= on NM_001625.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 58/212 reads (27%) | catalogued as rs773484833, COSV100710101; called by muse, mutect2, varscan2
- ANKRD12 | c.2157A>G p.T719= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV50819518; called by muse, mutect2, varscan2
- ANKRD17 | c.2103G>A p.L701= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as COSV58215719; called by muse, mutect2, varscan2
- ANKRD37 | c.69C>T p.V23= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV52990636; called by muse, mutect2, varscan2
- ANKRD40 | c.333G>T p.L111= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as rs1445784806, COSV53332799; called by muse, mutect2, varscan2
- APOB | c.9924T>C p.H3308= | Silent (SNP) | VAF 35/93 reads (38%) | catalogued as rs370661042; called by muse, mutect2, varscan2
- ARID5A | c.102G>A p.Q34= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV62590755; called by muse, mutect2, varscan2
- ATP13A5 | c.3609C>G p.L1203= | Silent (SNP) | VAF 32/224 reads (14%) | catalogued as COSV53230215; called by muse, mutect2, varscan2
- AZU1 | c.258G>A p.L86= | Silent (SNP) | VAF 29/120 reads (24%) | catalogued as rs1284634842, COSV52140178, COSV52141678; called by muse, mutect2, varscan2
- BCL6 | c.1347C>T p.I449= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as rs780615769, COSV51650112; called by muse, mutect2, varscan2
- BOD1L1 | c.6048C>T p.V2016= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV50006889; called by muse, mutect2, varscan2
- BORCS5 | c.210G>A p.L70= | Silent (SNP) | VAF 29/112 reads (26%) | catalogued as COSV53801187, COSV53802847; called by muse, mutect2, varscan2
- BRD9 | c.687C>T p.I229= | Silent (SNP) | VAF 74/888 reads (8%) | catalogued as COSV60244808; called by muse, mutect2
- C16orf87 | c.381C>T p.N127= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV53511591; called by muse, mutect2, varscan2
- C3orf20 | c.1155C>T p.F385= | Silent (SNP) | VAF 22/154 reads (14%) | catalogued as rs767835959, COSV53782675; called by muse, mutect2, varscan2
- CACNA1D | c.5610A>G p.R1870= (on ENST00000350061 / NM_001128840.3; = p.R1890= on NM_000720.4) | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as COSV55438438; called by muse, mutect2, varscan2
- CACNA2D2 | c.3135G>A p.Q1045= (on ENST00000479441 / NM_001174051.3; = p.Q1038= on NM_006030.4) | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV56560721; called by muse, mutect2, varscan2
- CALB1 | c.106C>T p.L36= | Silent (SNP) | VAF 53/161 reads (33%) | catalogued as COSV55366589, COSV55370219; called by muse, mutect2, varscan2
- CALR | c.438C>T p.V146= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as COSV57118578; called by muse, mutect2, varscan2
- CASZ1 | c.4302C>T p.F1434= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV65456278; called by muse, mutect2, varscan2
- CBLL1 | c.1182G>A p.Q394= | Silent (SNP) | VAF 53/177 reads (30%) | catalogued as COSV56028209; called by muse, mutect2, varscan2
- CBY1 | c.30G>A p.P10= | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as COSV53263876; called by muse, mutect2, varscan2
- CCDC62 | c.1761G>A p.L587= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV53430885; called by muse, mutect2, varscan2
- CCDC88A | c.2751G>A p.K917= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV55056830; called by muse, mutect2, varscan2
- CCDC88C | c.2160C>T p.S720= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV66234449; called by muse, mutect2, varscan2
- CDH20 | c.291C>A p.I97= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV53005133, COSV99403947; called by muse, mutect2, varscan2
- CEP290 | c.4710A>G p.Q1570= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs1180602962, COSV58358764; called by muse, mutect2
- CFAP58 | c.1191C>T p.V397= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as COSV57211371; called by muse, mutect2, varscan2
- CHD3 | c.5376C>T p.F1792= (on ENST00000330494 / NM_001005273.3; = p.F1758= on NM_005852.4) | Silent (SNP) | VAF 23/94 reads (24%) | catalogued as COSV57872743; called by muse, mutect2, varscan2
- CLEC17A | c.711C>T p.N237= | Silent (SNP) | VAF 21/39 reads (54%) | catalogued as COSV60426882; called by muse, mutect2, varscan2
- COL9A1 | c.129C>G p.L43= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as COSV61828859, COSV61838198; called by muse, mutect2, varscan2
- CPNE5 | c.867G>A p.P289= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as rs779507694, COSV55194843; called by muse, mutect2, varscan2
- CREG2 | c.849C>T p.F283= | Silent (SNP) | VAF 20/81 reads (25%) | catalogued as COSV61316066; called by muse, mutect2, varscan2
- DDX52 | c.762A>G p.L254= | Silent (SNP) | VAF 30/64 reads (47%) | catalogued as rs1001430178; called by muse, mutect2, varscan2
- DGKG | c.724C>T p.L242= | Silent (SNP) | VAF 44/178 reads (25%) | catalogued as COSV53961899; called by muse, mutect2, varscan2
- DISP3 | c.2964C>T p.F988= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as COSV53821099; called by muse, mutect2, varscan2
- DKK4 | c.27G>A p.L9= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV55182099; called by muse, mutect2, varscan2
- DNAH1 | c.10002G>T p.T3334= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV70226725; called by muse, mutect2, varscan2
- DNAH1 | c.11184C>T p.F3728= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV70226726; called by muse, mutect2, varscan2
- DNAH12 | c.1263C>G p.L421= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV60855655, COSV60858993; called by muse, mutect2, varscan2
- DNASE1L1 | c.408C>T p.S136= | Silent (SNP) | VAF 15/26 reads (58%) | catalogued as COSV50010011; called by muse, mutect2, varscan2
- DOCK10 | c.1069C>T p.L357= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs1354798225, COSV51349673; called by muse, mutect2, varscan2
- DYNC1H1 | c.9720G>T p.L3240= | Silent (SNP) | VAF 34/55 reads (62%) | catalogued as COSV64134627; called by muse, mutect2, varscan2
- EDEM2 | c.9C>T p.F3= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV65712593; called by muse, mutect2, varscan2
- EN1 | c.1020C>T p.L340= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV54630348; called by muse, mutect2, varscan2
- ETF1 | c.1044A>T p.P348= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV62126922; called by muse, mutect2, varscan2
- EXOC2 | c.627C>T p.L209= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as COSV57861530, COSV57862987; called by muse, mutect2, varscan2
- EXOG | c.1074G>A p.E358= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV55062671; called by muse, mutect2, varscan2
- FAM91A1 | c.225C>T p.L75= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as COSV58235815; called by muse, mutect2, varscan2
- FAT3 | c.2610C>T p.V870= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as COSV53079209, COSV53096666; called by muse, mutect2, varscan2
- FCRL3 | c.1554G>A p.G518= | Silent (SNP) | VAF 28/156 reads (18%) | catalogued as COSV63839599; called by muse, mutect2, varscan2
- FGF12 | c.141G>A p.G47= | Silent (SNP) | VAF 38/240 reads (16%) | catalogued as COSV53153854; called by muse, mutect2, varscan2
- FN3KRP | c.288G>C p.L96= | Silent (SNP) | VAF 39/85 reads (46%) | catalogued as COSV53928952; called by muse, mutect2, varscan2
- FNDC1 | c.1230C>T p.S410= | Silent (SNP) | VAF 60/282 reads (21%) | catalogued as COSV51931390; called by muse, mutect2, varscan2
- FOXG1 | c.876C>T p.L292= | Silent (SNP) | VAF 41/78 reads (53%) | catalogued as rs1236859265, COSV57395346; called by muse, mutect2, varscan2
- FOXN2 | c.1152G>A p.K384= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV61317124; called by muse, mutect2, varscan2
- FURIN | c.1629C>G p.P543= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs1258038452, COSV51574752; called by muse, mutect2, varscan2
- GBF1 | c.2859G>A p.Q953= (on ENST00000369983 / NM_001377137.1; = p.Q952= on NM_004193.3) | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV64143004; called by muse, mutect2, varscan2
- GCM2 | c.381G>A p.L127= | Silent (SNP) | VAF 22/114 reads (19%) | catalogued as COSV65275151; called by muse, mutect2, varscan2
- GLIS3 | c.24C>T p.L8= | Silent (SNP) | VAF 22/176 reads (13%) | catalogued as rs759784205, COSV60924389; called by muse, mutect2, varscan2
- GLRA3 | c.1200A>T p.P400= | Silent (SNP) | VAF 32/104 reads (31%) | catalogued as COSV56858140; called by muse, mutect2, varscan2
- GNA11 | c.924C>T p.F308= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV50017535; called by muse, mutect2, varscan2
- GNAQ | c.669C>T p.V223= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV54107663; called by muse, mutect2, varscan2
- GOLGA4 | c.4032G>A p.L1344= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV62709374; called by muse, mutect2, varscan2
- GPATCH2L | c.1362G>A p.V454= | Silent (SNP) | VAF 47/81 reads (58%) | catalogued as rs1428841297, COSV55046907; called by muse, mutect2, varscan2
- GPR89A | c.1290C>T p.F430= | Silent (SNP) | VAF 38/898 reads (4%) | called by muse, mutect2
- GRAMD2A | c.915G>A p.L305= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV59032730, COSV59033960; called by muse, mutect2, varscan2
- GRIN2D | c.726G>A p.Q242= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as COSV54377160; called by muse, mutect2, varscan2
- GSPT2 | c.144C>T p.F48= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV100468454; called by muse, mutect2, varscan2
- GSS | c.216C>T p.F72= | Silent (SNP) | VAF 27/102 reads (26%) | catalogued as COSV53811727; called by muse, mutect2, varscan2
- H1-10 | c.57G>A p.K19= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as COSV100412971; called by muse, mutect2
- HACD4 | c.354C>T p.F118= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as rs368096773; called by muse, mutect2
- HDAC2 | c.1152T>C p.A384= | Silent (SNP) | VAF 28/65 reads (43%) | catalogued as COSV64037414; called by muse, mutect2, varscan2
- HELB | c.2037A>G p.E679= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV56072286; called by muse, mutect2, varscan2
- HGFAC | c.1938G>A p.R646= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV66976618; called by muse, mutect2, varscan2
- HID1 | c.744C>T p.L248= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV100586043, COSV59351009; called by muse, mutect2, varscan2
- HYDIN | c.1422C>T p.F474= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV55477921; called by muse, mutect2, varscan2
- IRF2BP1 | c.750C>T p.H250= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as COSV56192968; called by muse, mutect2, varscan2
- ISLR2 | c.1350C>T p.L450= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs751528701, COSV100679838; called by muse, varscan2
- ITIH1 | c.1251C>G p.L417= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs1437061701, COSV56252288, COSV56256008; called by muse, mutect2, varscan2
- ITLN1 | c.261G>A p.E87= | Silent (SNP) | VAF 22/496 reads (4%) | catalogued as COSV58273914; called by muse, mutect2
- IZUMO1 | c.687C>T p.G229= | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as COSV55802752; called by muse, mutect2, varscan2
- JADE2 | c.675T>C p.C225= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV50911887; called by muse, mutect2, varscan2
- KBTBD7 | c.609C>T p.L203= | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as COSV65266113; called by muse, mutect2, varscan2
- KCNH7 | c.864C>T p.N288= | Silent (SNP) | VAF 28/85 reads (33%) | catalogued as COSV59786303, COSV59797391; called by muse, mutect2, varscan2
- KCTD14 | c.45G>A p.T15= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs201802138, COSV62001080; called by muse, mutect2, varscan2
- KDM6A | c.2232C>T p.V744= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs35467614, COSV65036839; ClinVar: benign; called by muse, mutect2, varscan2
- KIAA1109 | c.11790C>T p.S3930= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV52663167; called by muse, mutect2, varscan2
- KLHL24 | c.1710T>C p.S570= | Silent (SNP) | VAF 26/127 reads (20%) | catalogued as COSV54424787; called by muse, mutect2, varscan2
- KLHL42 | c.654C>T p.S218= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs1172429164, COSV67145637; called by muse, mutect2, varscan2
- KMT2A | c.9606C>T p.S3202= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as COSV63282414, COSV63289423; called by muse, mutect2, varscan2
- KMT2B | c.4803C>T p.I1601= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs748448069, COSV55857521; called by muse, mutect2, varscan2
- KPNA5 | c.1044G>A p.L348= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV62651210; called by muse, mutect2, varscan2
- LAMTOR2 | c.75G>A p.L25= | Silent (SNP) | VAF 40/239 reads (17%) | catalogued as rs752983593, COSV64145036; called by muse, mutect2, varscan2
- LDLRAP1 | c.132G>A p.E44= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV65473166; called by muse, mutect2, varscan2
- LHX1 | c.597C>T p.F199= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs1375807844; called by muse, mutect2
- LRBA | c.7923C>T p.V2641= | Silent (SNP) | VAF 28/86 reads (33%) | catalogued as COSV63950330; called by muse, mutect2, varscan2
- MAP1A | c.1884G>A p.Q628= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs1235770966, COSV100289405; called by muse, mutect2, varscan2
- MAU2 | c.399G>A p.A133= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as rs764595627, COSV53233709; called by muse, mutect2, varscan2
- MBOAT7 | c.1287C>T p.I429= | Silent (SNP) | VAF 43/103 reads (42%) | catalogued as COSV55474470, COSV55474954; called by muse, mutect2, varscan2
- ME1 | c.819A>G p.T273= | Silent (SNP) | VAF 3/39 reads (8%) | catalogued as COSV100866722; called by muse, mutect2
- MED22 | c.108C>A p.I36= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as rs1307053866, COSV59297214; called by muse, mutect2, varscan2
- MEIS1 | c.183C>T p.P61= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs1430217462, COSV99715921; called by muse, mutect2, varscan2
- MFN1 | c.1656C>T p.I552= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV54938208; called by muse, mutect2, varscan2
- MID1 | c.657G>A p.L219= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as COSV58191832; called by muse, mutect2, varscan2
- MINPP1 | c.549C>T p.S183= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV100916800; called by muse, mutect2, varscan2
- MIOS | c.1654C>T p.L552= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as rs1441257489, COSV60767120; called by muse, mutect2, varscan2
- MPI | c.1216C>T p.L406= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as rs1268364682, COSV60396360; ClinVar: likely benign; called by muse, mutect2, varscan2
- MRPL40 | c.516G>A p.E172= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as rs375750071; called by muse, mutect2, varscan2
- MRPL53 | c.338G>A p.*113= | Silent (SNP) | VAF 30/85 reads (35%) | catalogued as COSV99251992; called by muse, mutect2, varscan2
- MSH2 | c.2685C>G p.P895= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV51875898; called by muse, mutect2, varscan2
- MTARC1 | c.387C>T p.A129= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV65055208; called by muse, mutect2, varscan2
- MTFR1L | c.878G>A p.*293= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV100961988; called by muse, mutect2, varscan2
- MYO3A | c.4488C>A p.P1496= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as COSV56320742, COSV99779441; called by muse, mutect2, varscan2
- NEB | c.681G>C p.L227= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as COSV50817373, COSV99427478; called by muse, mutect2, varscan2
- NEK3 | c.756C>G p.L252= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV51615617, COSV51617037; called by muse, mutect2, varscan2
- NFAT5 | c.2706G>A p.Q902= | Silent (SNP) | VAF 27/43 reads (63%) | catalogued as COSV63025368; called by muse, mutect2, varscan2
- NLRC5 | c.2811C>T p.H937= | Silent (SNP) | VAF 81/132 reads (61%) | catalogued as COSV52649744; called by muse, mutect2, varscan2
- NLRP14 | c.1377T>C p.S459= | Silent (SNP) | VAF 27/61 reads (44%) | catalogued as COSV55064375; called by muse, mutect2, varscan2
- NLRP8 | c.993G>A p.L331= | Silent (SNP) | VAF 48/126 reads (38%) | catalogued as COSV52583698; called by muse, mutect2, varscan2
- NOL8 | c.2223T>C p.S741= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as COSV62634194; called by muse, mutect2, varscan2
- NOTCH2 | c.4545C>T p.D1515= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV56682731, COSV56697189; called by muse, mutect2, varscan2
- NPY1R | c.453T>C p.N151= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as COSV56713413; called by muse, mutect2, varscan2
- NR1I3 | c.318G>A p.L106= | Silent (SNP) | VAF 53/1256 reads (4%) | catalogued as COSV63467238; called by muse, mutect2
- OBSCN | c.2736C>T p.C912= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as rs757436825, COSV52744197; called by muse, mutect2, varscan2
- OR10G8 | c.255C>T p.F85= | Silent (SNP) | VAF 56/178 reads (31%) | catalogued as COSV70908146; called by muse, mutect2, varscan2
- OR14K1 | c.741T>C p.T247= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV51720391; called by muse, mutect2, varscan2
- OR1L8 | c.516C>A p.S172= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV59185793; called by muse, mutect2, varscan2
- OR3A2 | c.451A>C p.R151= | Silent (SNP) | VAF 23/129 reads (18%) | catalogued as COSV68694941; called by muse, mutect2, varscan2
- OR4N5 | c.594G>A p.L198= | Silent (SNP) | VAF 32/129 reads (25%) | catalogued as COSV61320095; called by muse, mutect2, varscan2
- OR5W2 | c.492C>T p.F164= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV60614706, COSV60619192; called by muse, mutect2, varscan2
- OR9K2 | c.741G>A p.V247= (on ENST00000305377; = p.V225= on NM_001005243.1) | Silent (SNP) | VAF 37/91 reads (41%) | catalogued as COSV59531429; called by muse, mutect2, varscan2
- OVOL2 | c.522C>T p.P174= | Silent (SNP) | VAF 34/144 reads (24%) | catalogued as COSV53859577; called by muse, mutect2, varscan2
- OXCT1 | c.1254G>A p.K418= | Silent (SNP) | VAF 60/126 reads (48%) | catalogued as COSV52167602, COSV99541629; called by muse, mutect2, varscan2
- P2RY1 | c.948C>T p.N316= | Silent (SNP) | VAF 20/145 reads (14%) | catalogued as COSV59308899; called by muse, mutect2, varscan2
- P4HB | c.438A>G p.A146= | Silent (SNP) | VAF 37/77 reads (48%) | catalogued as rs1297449053, COSV58940052; called by muse, mutect2, varscan2
- PALD1 | c.2400C>T p.F800= | Silent (SNP) | VAF 33/97 reads (34%) | catalogued as COSV54971029; called by muse, mutect2, varscan2
- PCDHB5 | c.1620G>A p.L540= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV50647460; called by muse, mutect2, varscan2
- PDK3 | c.147A>G p.L49= | Silent (SNP) | VAF 18/33 reads (55%) | catalogued as COSV64792864; called by muse, mutect2, varscan2
- PGRMC1 | c.78C>T p.F26= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV54293303; called by muse, mutect2, varscan2
- PHF14 | c.1176T>C p.D392= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV68854272, COSV68856870; called by muse, mutect2
- PHLDB2 | c.765A>G p.S255= | Silent (SNP) | VAF 49/107 reads (46%) | catalogued as rs1559885288, COSV67308439; called by muse, mutect2, varscan2
- PIK3CB | c.2817A>G p.G939= | Silent (SNP) | VAF 23/51 reads (45%) | catalogued as COSV56683582; called by muse, mutect2, varscan2
- PKDREJ | c.2580C>T p.N860= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as rs1337992052, COSV53546639; called by muse, mutect2, varscan2
- PLB1 | c.3219T>C p.C1073= | Silent (SNP) | VAF 23/104 reads (22%) | catalogued as COSV59819772; called by muse, mutect2, varscan2
- PNKP | c.528C>T p.L176= | Silent (SNP) | VAF 39/126 reads (31%) | catalogued as rs749645305, COSV55586478, COSV55586605; called by muse, mutect2, varscan2
- POM121C | c.1059C>T p.L353= (on ENST00000607367; = p.L111= on NM_001099415.3) | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as rs782647192, COSV99993169; called by muse, mutect2, varscan2
- POU2F2 | c.732C>T p.F244= (on ENST00000526816 / NM_001207025.3; = p.F228= on NM_002698.5) | Silent (SNP) | VAF 25/104 reads (24%) | catalogued as rs756460030, COSV60759957; called by muse, mutect2, varscan2
- PPRC1 | c.1038G>A p.L346= | Silent (SNP) | VAF 38/169 reads (22%) | catalogued as COSV53383361; called by muse, mutect2, varscan2
- PSMD11 | c.597C>T p.A199= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as rs747325041, COSV55577452; called by muse, mutect2, varscan2
- PSMD4 | c.984G>C p.V328= | Silent (SNP) | VAF 46/458 reads (10%) | catalogued as COSV64393075; called by muse, mutect2
- PTPRC | c.1747C>T p.L583= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as rs1253820923, COSV61406898, COSV61407383; called by muse, mutect2, varscan2
- PTPRS | c.846C>T p.A282= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs769128497, COSV53610864; called by muse, mutect2, varscan2
- PUM1 | c.684A>G p.S228= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV57082018; called by muse, mutect2, varscan2
- PUS3 | c.1062T>C p.N354= | Silent (SNP) | VAF 44/105 reads (42%) | catalogued as COSV57102180; called by muse, mutect2, varscan2
- QPCT | c.372C>T p.I124= | Silent (SNP) | VAF 23/117 reads (20%) | catalogued as COSV58119097; called by muse, mutect2, varscan2
- QRICH2 | c.2028C>A p.V676= | Silent (SNP) | VAF 28/116 reads (24%) | catalogued as COSV53151123, COSV53152755, COSV53156698; called by muse, mutect2, varscan2
- RAB40AL | c.450G>A p.V150= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as COSV54433646; called by muse, mutect2, varscan2
- RALGDS | c.2739C>T p.I913= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as rs1486583138, COSV64425759; called by muse, mutect2, varscan2
- RAMP1 | c.153C>T p.V51= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as rs377248643; called by muse, mutect2, varscan2
- RAP2A | c.255C>T p.V85= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV55354405; called by muse, mutect2, varscan2
- RASAL2 | c.1305C>T p.F435= | Silent (SNP) | VAF 22/109 reads (20%) | catalogued as COSV62710196; called by muse, mutect2, varscan2
- RBP4 | c.54G>A p.A18= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as rs778553827, COSV65159649; called by muse, mutect2, varscan2
- RHOJ | c.75G>A p.V25= | Silent (SNP) | VAF 23/41 reads (56%) | catalogued as rs773136162, COSV104414445, COSV57456795; called by muse, mutect2, varscan2
- RNF150 | c.1242G>A p.L414= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV60787042; called by muse, mutect2, varscan2
- RNF217 | c.288C>T p.L96= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV71376424; called by muse, mutect2, varscan2
- RPL7 | c.327G>A p.L109= | Silent (SNP) | VAF 33/96 reads (34%) | catalogued as COSV53581365; called by muse, mutect2, varscan2
- RSPH10B2 | c.1626G>A p.E542= | Silent (SNP) | VAF 18/108 reads (17%) | catalogued as rs746375128, COSV99786459; called by muse, mutect2, varscan2
- RTP2 | c.588C>T p.F196= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV64078812, COSV64079133; called by muse, mutect2, varscan2
- RYR3 | c.13557A>G p.L4519= (on ENST00000389232; = p.L4520= on NM_001036.6) | Silent (SNP) | VAF 32/67 reads (48%) | catalogued as rs923943676, COSV66778991; called by muse, mutect2, varscan2
- SCUBE1 | c.2340C>A p.T780= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV62610343; called by muse, mutect2, varscan2
- SEPTIN4 | c.1260G>A p.V420= | Silent (SNP) | VAF 71/175 reads (41%) | catalogued as COSV57894470; called by muse, mutect2, varscan2
- SESN1 | c.81C>T p.N27= | Silent (SNP) | VAF 31/117 reads (26%) | catalogued as COSV61244233; called by muse, mutect2, varscan2
- SIRPA | c.555C>T p.F185= | Silent (SNP) | VAF 36/104 reads (35%) | catalogued as COSV61536848; called by muse, mutect2, varscan2
- SKAP2 | c.1032C>T p.A344= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV61721608; called by muse, mutect2, varscan2
- SLC9A3 | c.1086C>T p.F362= | Silent (SNP) | VAF 4/67 reads (6%) | called by muse, mutect2
- SLC9C1 | c.1566A>G p.A522= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as COSV59885319, COSV99998631; called by muse, mutect2, varscan2
- SLITRK1 | c.1929G>C p.L643= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV65674412; called by muse, mutect2, varscan2
- SLITRK3 | c.735T>C p.S245= | Silent (SNP) | VAF 49/109 reads (45%) | catalogued as rs140320748; called by muse, mutect2, varscan2
- SOX4 | c.393G>A p.R131= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs1291043982, COSV99781976, COSV99782223; called by muse, mutect2
- SRPRB | c.183G>A p.R61= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as COSV71749018; called by muse, mutect2
- ST18 | c.780G>A p.Q260= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as COSV52485239; called by muse, mutect2, varscan2
- ST3GAL1 | c.654G>C p.V218= | Silent (SNP) | VAF 29/82 reads (35%) | catalogued as COSV60610649; called by muse, mutect2, varscan2
- TIMD4 | c.273G>A p.P91= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as rs774244018, COSV50854024, COSV99192883; called by muse, mutect2, varscan2
- TMEM131L | c.2109C>G p.L703= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as COSV53641480; called by muse, mutect2, varscan2
- TMEM132E | c.1839G>C p.G613= (on ENST00000321639; = p.G703= on NM_001304438.2) | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV58694888, COSV58694921; called by muse, mutect2
- TMEM230 | c.249G>A p.L83= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as COSV52531717; called by muse, mutect2, varscan2
- TMEM245 | c.1143G>A p.P381= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs746689622, COSV65822253; called by muse, mutect2
- TNXB | c.10719C>T p.Y3573= (on ENST00000647633; = p.Y3326= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/65 reads (48%) | catalogued as COSV64474108; called by muse, mutect2, varscan2
- TOPORS | c.1539G>A p.V513= | Silent (SNP) | VAF 18/150 reads (12%) | catalogued as COSV62116215; called by muse, mutect2, varscan2
- TRBJ2-5 | c.21C>T p.F7= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as rs782050361; called by muse, mutect2, varscan2
- TSPAN14 | c.327C>G p.A109= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as rs761571527, COSV100540252, COSV59367105; called by muse, mutect2, varscan2
- TTC21A | c.1029C>T p.L343= | Silent (SNP) | VAF 25/96 reads (26%) | catalogued as COSV57183228; called by muse, mutect2, varscan2
- TTC5 | c.450G>A p.R150= | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as COSV51870218; called by muse, mutect2, varscan2
- TULP4 | c.570G>A p.Q190= | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as rs768079047, COSV65572415; called by muse, mutect2, varscan2
- TWF2 | c.924C>G p.L308= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as rs1475108275, COSV59725790; called by muse, mutect2, varscan2
- UBIAD1 | c.132G>A p.Q44= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as COSV65147535, COSV65147999; called by muse, mutect2, varscan2
- USP31 | c.2187G>A p.K729= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as COSV54849588; called by muse, mutect2, varscan2
- USP4 | c.2469C>T p.V823= | Silent (SNP) | VAF 23/105 reads (22%) | catalogued as rs1401932060, COSV55535037; called by muse, mutect2, varscan2
- USP53 | c.2406C>A p.P802= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV56792512; called by muse, mutect2, varscan2
37 further variants in this file (0 protein-altering or splice-affecting, 13 silent, 24 other) are not listed here.
